Gene-level copy-number profile of tumor specimen C3L-02365-01 from CPTAC case C3L-02365, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 62.8 years (22,934 days).
Specimen C3L-02365-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe1e5e5c-e84b-40e5-8673-7219f634b61f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02365-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/591f4655-e90d-413f-bb4f-111a88073e5d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 206; copy number 2: 2,248; copy number 3: 5,543; copy number 4: 20,608; copy number 5: 8,463; copy number 6: 7,910; copy number 7: 5,786; copy number 8: 2,682; copy number 9: 512; copy number 10: 2,999; copy number 11: 330; copy number 12: 165; copy number 13: 669; copy number 14: 75; copy number 15: 9; copy number 16: 89; copy number 17: 23; copy number 18: 14; copy number 19: 4; copy number 20: 26; copy number 22: 29; copy number 27: 4.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–180,970,762, 2 genes: AC091874.2, AC091874.1.
- chr8:7,891,003–7,896,716, 2 genes: HSPD1P2, DEFB4A.
- chr18:31,937,533–31,944,156, 2 genes (within-gene range 0–4): RNU6-1050P, AC009831.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,948 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,608,106–163,923,873, 110 genes, copy number 10 (broad region; genes not listed).
- chr1:174,998,353–175,743,616, 12 genes, copy number 10: Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1, TNR, TNR-IT1.
- chr1:196,774,813–196,795,407, 1 gene, copy number 10: CFHR3.
- chr1:245,749,342–246,507,312, 1 gene, copy number 11 (within-gene range 6–16): SMYD3.
- chr1:246,108,626–248,937,043, 132 genes, copy number 11–20 (within-gene range 6–20) (broad region; genes not listed).
- chr2:105,241,743–112,742,879, 169 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr2:117,754,139–117,832,377, 2 genes, copy number 9: AC009312.1, DDX18.
- chr2:237,257,091–240,080,362, 60 genes, copy number 9: AC112715.1, COL6A3, AC112721.1, AC112721.2, MLPH, MIR6811, RNU6-1140P, PRLH, RAB17, AC104667.2, AC104667.1, LRRFIP1, AC012076.1, RBM44, RAMP1, SNORD39, UBE2F, UBE2F-SCLY, RNU6-1333P, SCLY, ESPNL, KLHL30, KLHL30-AS1, ERFE, ILKAP, LINC02610, AC012485.1, HES6, PER2, AC012485.3, AC012485.2, TRAF3IP1, RNU6-234P, ASB1, AC016999.1, AC016999.2, LINC01107, LINC01937, AC113618.2, AC113618.1, AC145625.1, TWIST2, LINC01940, HDAC4, MIR4440, MIR4441, AC017028.1, AC017028.2, MIR4269, MIR2467, HDAC4-AS1, AC079612.1, AC079612.2, AC093802.2, AC093802.1, NDUFA10, MIR4786, OR6B2, OR6B3, OR9S24P.
- chr3:130,048,143–130,055,920, 1 gene, copy number 11: AC083906.4.
- chr4:39,528,019–40,167,831, 23 genes, copy number 10 (within-gene range 4–10): UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2, UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP, PDS5A, ELOCP33, RNA5SP159, AC098591.3, PABPC1P1, KRT18P25, AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3.
- chr5:58,198–51,275,734, 694 genes, copy number 9–14 (broad region; genes not listed).
- chr5:52,787,916–54,310,582, 24 genes, copy number 10 (within-gene range 3–10): PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1.
- chr7:37,032–8,939,369, 201 genes, copy number 9–15 (broad region; genes not listed).
- chr7:10,207,670–11,520,175, 13 genes, copy number 10–16 (within-gene range 8–16): AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11.
- chr7:11,406,955–11,414,078, 1 gene, copy number 10 (within-gene range 8–10): AC004160.2.
- chr7:12,876,684–12,922,920, 2 genes, copy number 13: RN7SKP228, RBMX2P4.
- chr7:15,611,212–18,027,846, 39 genes, copy number 10–16: MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1.
- chr7:21,220,213–21,381,506, 2 genes, copy number 20: ASS1P11, RNU1-15P.
- chr7:22,725,395–23,311,729, 18 genes, copy number 10 (within-gene range 8–10): IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1.
- chr7:26,152,198–26,201,529, 2 genes, copy number 12 (within-gene range 8–12): NFE2L3, HNRNPA2B1.
- chr7:29,514,224–41,133,507, 214 genes, copy number 9–27 (within-gene range 8–27) (broad region; genes not listed).
- chr7:44,143,213–44,334,577, 3 genes, copy number 19–20: GCK, YKT6, CAMK2B.
- chr7:44,379,119–44,541,330, 5 genes, copy number 16: NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1.
- chr7:44,748,581–56,323,601, 177 genes, copy number 9–13 (broad region; genes not listed).
- chr7:68,640,798–148,420,998, 1,464 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr8:47,260,878–145,066,685, 1,466 genes, copy number 10–11 (broad region; genes not listed).
- chr11:48,263,861–48,366,465, 5 genes, copy number 9: OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5.
- chr14:35,538,352–38,041,442, 45 genes, copy number 10–11 (within-gene range 8–11): RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P.
- chr14:39,114,223–40,390,547, 14 genes, copy number 10 (within-gene range 7–10): GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1.
- chr18:30,713,275–30,780,424, 2 genes, copy number 13: AC090506.1, AC090506.2.
- chr20:51,098,138–55,075,140, 46 genes, copy number 12: AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4.

Autosomal genes at a single copy (total copy number 1): 206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
